Somatic mutation profile of tumor specimen TCGA-L5-A8NS-01A (aliquot TCGA-L5-A8NS-01A-12D-A37C-09) from TCGA case TCGA-L5-A8NS, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 76.1 years (27,800 days).
Specimen TCGA-L5-A8NS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31f146d1-ea0c-420d-a9d6-a4a9174b3b59.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NS-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NS-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8fb2f4bf-654a-4b27-bc3a-1364936c897f

The open-access MAF lists 394 somatic variants for this specimen: 309 protein-altering or splice-affecting, 71 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 262, Silent 71, Nonsense Mutation 17, Frame Shift Del 16, Intron 8, Splice Site 8, In Frame Del 6, 5'UTR 2, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PAX6 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as rs1057517785, CM930573, COSV99570800; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 15/33 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- USH1G | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as rs538983393; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABT1 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as rs151288548; called by muse, mutect2, varscan2
- ACSBG1 | c.1415C>T p.A472V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs774668709, COSV51906562; called by muse, mutect2, varscan2
- AGRN | c.2732G>A p.R911Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.089); catalogued as rs773144997; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALDH1A1 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as rs778276187, COSV52789879; called by muse, mutect2, varscan2
- AMPD1 | c.2047G>T p.D683Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62415313; called by muse, mutect2, varscan2
- ANKRD30A | c.2780G>A p.S927N (on ENST00000611781; = p.S871N on NM_052997.2) | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV64611974; called by muse, mutect2
- AQP1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.95); catalogued as rs898407370, COSV61266523; called by muse, mutect2
- ARRDC2 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs369910146, COSV55843844; called by muse, mutect2, varscan2
- ASTN1 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1364819044; called by muse, mutect2, varscan2
- ATP2A1 | c.1666C>T p.R556W | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs760705868, COSV100837032; called by muse, mutect2, varscan2
- AVL9 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as rs372188373; called by muse, mutect2, varscan2
- BBS7 | c.1057C>A p.Q353K | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV52659881; called by muse, mutect2
- C1QL4 | c.577T>C p.Y193H | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1469557748; called by muse, mutect2, varscan2
- CCND3 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as COSV65913381; called by muse, mutect2, varscan2
- CFAP69 | c.1432G>C p.A478P | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.231); catalogued as COSV60184377; called by muse, mutect2, varscan2
- COL11A1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100614875; called by muse, varscan2
- COL27A1 | c.4856G>A p.G1619E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs1024841090, COSV61927457; called by muse, mutect2
- CPS1 | c.2162G>A p.R721Q | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752339705, CM114345, COSV51818176, COSV51823423; called by muse, mutect2, varscan2
- CYP11B1 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs369213890; called by muse, mutect2, varscan2
- DCBLD2 | c.1676A>G p.K559R | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); catalogued as rs1243910584; called by muse, mutect2
- DISP3 | c.1885A>G p.T629A | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs1410271290; called by muse, mutect2, varscan2
- DNAH2 | c.6545T>C p.M2182T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs944566336; called by muse, mutect2, varscan2
- DNAH3 | c.896T>A p.I299N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1186558478; called by muse, mutect2
- DOCK2 | c.2709C>A p.F903L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV56961940; called by muse, mutect2, varscan2
- DSCAM | c.4645C>T p.R1549W | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs779003144, COSV101260082; called by muse, mutect2, varscan2
- DSCAML1 | c.1255G>A p.E419K (on ENST00000321322; = p.E359K on NM_020693.4) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.68); PolyPhen benign (0.146); catalogued as rs921896794, COSV58386582; called by muse, mutect2
- EHBP1L1 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367950334; called by muse, mutect2, varscan2
- ELAPOR2 | c.1175A>G p.K392R (on ENST00000450689 / NM_001142749.3; = p.K225R on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as rs1272222580; called by muse, mutect2, varscan2
- FAM13B | c.1308G>C p.K436N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99221989; called by muse, mutect2, varscan2
- FANCA | c.3239G>T p.R1080L | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.607); catalogued as CM050611, CM146018, COSV59796386; called by muse, mutect2, varscan2
- FCHSD2 | c.842A>G p.Y281C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.527); catalogued as rs758027410; called by muse, mutect2, varscan2
- FOXD4L4 | c.304G>T p.D102Y | Missense Mutation (SNP) | VAF 25/250 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV66219621; called by muse, varscan2
- FRA10AC1 | c.399G>C p.K133N | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV63271803; called by muse, mutect2
- GAD1 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs765841229, COSV64026197; called by muse, mutect2, varscan2
- GRIK4 | c.2297C>A p.A766D | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101483566; called by muse, mutect2, varscan2
- HSPG2 | c.230G>C p.G77A | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV101020584, COSV101020615; called by muse, mutect2, varscan2
- IGDCC4 | c.3667C>T p.P1223S | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1342979863; called by muse, mutect2
- JADE1 | c.1416T>G p.D472E | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.62); catalogued as COSV56904130; called by muse, mutect2, varscan2
- KIRREL3 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 18/146 reads (12%) | catalogued as COSV101585572; called by muse, mutect2, varscan2
- KSR1 | c.652G>A p.A218T (on ENST00000644974 / NM_001367810.1; = p.A81T on NM_014238.2) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV99257912; called by muse, mutect2, varscan2
- LATS2 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775892552, COSV66880529; called by muse, mutect2, varscan2
- LRP4 | c.5258A>C p.K1753T | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV66137732; called by muse, mutect2
- LRRC66 | c.1196C>A p.P399H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58634008; called by muse, mutect2, varscan2
- MATN1 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs141354318; called by muse, mutect2, varscan2
- MTSS2 | c.96C>G p.F32L | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs759606776; called by muse, mutect2, varscan2
- MUC17 | c.8303C>T p.A2768V | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.739); catalogued as rs768624828; called by muse, mutect2, varscan2
- MUSK | c.2443G>A p.V815M | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs551520537, COSV51877474; called by muse, mutect2, varscan2
- MYH1 | c.3122C>A p.S1041Y | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV56845370; called by muse, mutect2, varscan2
- NANS | c.514G>A p.V172M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.094); catalogued as rs758657004; called by muse, mutect2, varscan2
- NCAM1 | c.1172G>C p.G391A (on ENST00000316851 / NM_181351.5; = p.G381A on NM_000615.7) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as COSV100376873; called by muse, mutect2, varscan2
- NDST4 | c.1052A>C p.K351T | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52109442; called by muse, mutect2
- NELL1 | c.1000A>C p.K334Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.838); catalogued as COSV54335955; called by muse, mutect2, varscan2
- NYAP2 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV56001087; called by muse, mutect2, varscan2
- OR1B1 | c.6G>A p.M2I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1418053641, COSV104395893; called by muse, mutect2
- PABPC5 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198472403; called by muse, mutect2, varscan2
- PAK6 | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs768072309; called by muse, mutect2, varscan2
- PCDHB3 | c.2033C>T p.P678L | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.005); catalogued as rs1554272641, COSV99164395; called by muse, mutect2, varscan2
- PCDHB8 | c.1592G>A p.R531Q | Missense Mutation (SNP) | VAF 91/473 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.044); catalogued as COSV50754429; called by muse, mutect2, varscan2
- PEG3 | c.2282A>C p.K761T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV55627288, COSV99688396; called by muse, mutect2, varscan2
- PLA2G4F | c.2259G>T p.E753D | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV99300245; called by muse, mutect2, varscan2
- PPP6R2 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.091); catalogued as rs550603081, COSV53298816; called by muse, mutect2, varscan2
- PRKCQ | c.1886G>A p.R629H | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs951226172, COSV54105473; called by muse, mutect2, varscan2
- PRSS36 | c.2228G>A p.G743D | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.75); catalogued as rs867128154; called by muse, mutect2, varscan2
- RAB11FIP1 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1158693442; called by muse, mutect2
- SCAF1 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100862098; called by muse, mutect2, varscan2
- SEC16B | c.2557A>T p.I853F | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as rs943612200; called by muse, mutect2, varscan2
- SF3B3 | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.142); catalogued as COSV100210168; called by muse, mutect2
- SLC9C1 | c.352A>T p.N118Y | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59892155; called by muse, mutect2, varscan2
- SLF2 | c.506G>A p.R169Q | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs564996877, COSV53275025, COSV99488706; called by muse, mutect2, varscan2
- SOX10 | c.451C>G p.R151G | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as CM133726; called by muse, mutect2
- SPATS2L | c.1355C>T p.S452L | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1357567058; called by muse, mutect2, varscan2
- SYNE1 | c.18705A>C p.K6235N (on ENST00000367255 / NM_182961.4; = p.K6164N on NM_033071.3) | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99573292; called by muse, mutect2, varscan2
- TAS2R7 | c.353T>A p.L118H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV53690773; called by muse, mutect2, varscan2
- TEKT5 | c.403G>T p.E135* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV51587221; called by muse, mutect2
- TENM3 | c.1591G>A p.G531R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69308344; called by muse, mutect2, varscan2
- TET1 | c.2675T>C p.V892A | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.53); catalogued as rs780287566; called by muse, mutect2, varscan2
- TM9SF2 | c.710C>T p.P237L | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100899701; called by muse, mutect2, varscan2
- TNFRSF4 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.637); catalogued as rs755162827; called by muse, mutect2
- TRAPPC5 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs1325627776; called by muse, mutect2
- TRIOBP | c.4376G>A p.W1459* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as rs1215991486; called by muse, mutect2, varscan2
- TRRAP | c.2425C>G p.L809V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62841158; called by muse, mutect2, varscan2
- TSC22D2 | c.1574C>T p.S525F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs139411630; called by muse, mutect2, varscan2
- TSPAN31 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs568048822, COSV99223684; called by muse, mutect2, varscan2
- TTC16 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs377723581, COSV64781319; called by muse, mutect2, varscan2
- TTN | c.9611G>A p.R3204Q (on ENST00000591111; = p.R3158Q on NM_003319.4) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | PolyPhen possibly damaging (0.67); catalogued as rs775137389; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBR1 | c.3155A>C p.Y1052S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.69); catalogued as COSV51931904; called by muse, mutect2, varscan2
- VPS13A | c.3890G>T p.R1297L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV62437861; called by muse, mutect2, varscan2
- VPS37C | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs751202506; called by muse, mutect2, varscan2
- ZC3H15 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.677); catalogued as COSV100552205; called by muse, mutect2
- ZNF98 | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.419); catalogued as COSV63334412; called by muse, mutect2, varscan2
- ABCD2 | c.1889_1904del p.A630Vfs*27 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | called by mutect2, pindel, varscan2
- ABHD15 | c.916_939del p.S306_S313del | In Frame Del (DEL) | VAF 8/76 reads (11%) | called by mutect2, pindel
- ACACA | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.953); called by muse, mutect2
- ACSL3 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACTN3 | c.1564G>T p.D522Y | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ADGRV1 | c.7403C>A p.S2468* | Nonsense Mutation (SNP) | VAF 21/49 reads (43%) | called by muse, mutect2, varscan2
- AHCYL1 | c.1444T>C p.Y482H | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- AKAP9 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- AKAP9 | c.3336G>C p.Q1112H | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AKAP9 | c.7313A>G p.N2438S (on ENST00000359028; = p.N2414S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ALAD | c.325A>G p.R109G | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.146); called by muse, mutect2
- ALDH1L2 | c.1687-2A>C p.X563_splice | Splice Site (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- ANK2 | c.10037C>A p.S3346Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ANKRD12 | c.4126G>A p.A1376T | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARC | c.719C>A p.S240Y | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARHGAP31 | c.2480G>T p.S827I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- ATF7 | c.419C>T p.P140L (on ENST00000548446 / NM_001366555.2; = p.P129L on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.057); called by muse, mutect2
- ATM | c.3344T>C p.L1115P | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- ATP8B3 | c.1012G>A p.G338S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ATR | c.4987A>G p.T1663A | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.7); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AZI2 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- BHLHE22 | c.842C>G p.S281C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BNIP2 | c.463A>T p.S155C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CA14 | c.522T>G p.Y174* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- CARD11 | c.1232_1264del p.E411_M421del | In Frame Del (DEL) | VAF 8/51 reads (16%) | called by mutect2, pindel
- CATSPERD | c.658-2A>T p.X220_splice | Splice Site (SNP) | VAF 17/73 reads (23%) | called by muse, mutect2, varscan2
- CCAR2 | c.1417C>T p.Q473* | Nonsense Mutation (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- CCDC157 | c.1304C>G p.A435G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- CCDC38 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CCDC88A | c.172A>C p.K58Q | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CD244 | c.470G>A p.C157Y (on ENST00000368033 / NM_001166663.2; = p.C152Y on NM_016382.4) | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH7 | c.1784A>G p.N595S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDHR3 | c.2104A>C p.K702Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2
- CDK13 | c.3170A>C p.N1057T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- CDKN2AIP | c.597G>C p.Q199H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- CEMIP2 | c.953C>G p.A318G | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.037); called by muse, mutect2
- CEP290 | c.1174C>G p.L392V | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- CEP63 | c.1466A>T p.E489V | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- CHD8 | c.4821G>C p.E1607D (on ENST00000646647 / NM_001170629.2; = p.E1328D on NM_020920.4) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CHST1 | c.957C>A p.F319L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, mutect2, varscan2
- CLCA2 | c.1283A>G p.N428S | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTN2 | c.1910C>T p.P637L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COA7 | c.2_35del p.M1_?12 | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | called by mutect2, pindel
- CRP | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSTF3 | c.251T>A p.V84D | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CYFIP1 | c.3332G>A p.G1111E | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYP4F22 | c.247C>A p.Q83K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCLK1 | c.1134A>C p.E378D | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DERA | c.257C>G p.A86G | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DICER1 | c.3953T>G p.L1318R | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- DIXDC1 | c.818G>A p.G273E (on ENST00000440460 / NM_001037954.4; = p.G62E on NM_033425.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- DMXL1 | c.3829_3857del p.P1277Dfs*27 | Frame Shift Del (DEL) | VAF 12/40 reads (30%) | called by mutect2, pindel
- DNAH10 | c.12170A>T p.N4057I (on ENST00000409039; = p.N3996I on NM_207437.3) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.11498G>T p.G3833V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- DOCK2 | c.5022G>C p.K1674N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DPP4 | c.1787G>C p.R596T | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DPP4 | c.1558A>T p.N520Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DSC2 | c.982A>C p.M328L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- EED | c.174C>G p.N58K | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.52); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- EIF3L | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EIF5B | c.1296A>T p.E432D | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- FAM111B | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FARP1 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- FBXL5 | c.635T>C p.V212A | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FBXO3 | c.560G>A p.R187K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FBXO4 | c.335del p.S112Lfs*10 | Frame Shift Del (DEL) | VAF 20/58 reads (34%) | called by mutect2, pindel, varscan2
- FCHO2 | c.1847+4_1847+27del p.X616_splice | Splice Site (DEL) | VAF 8/32 reads (25%) | called by mutect2, pindel, varscan2
- FCRL5 | c.646T>C p.S216P | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.055); called by muse, mutect2
- FERD3L | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- FEZ1 | c.482T>G p.L161R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FLNC | c.5403G>C p.E1801D | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- FN1 | c.1635C>A p.C545* | Nonsense Mutation (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- FOXO3 | c.722G>C p.G241A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- FSTL1 | c.577C>G p.L193V | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- GFM1 | c.2146G>C p.E716Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GFPT1 | c.1272C>G p.D424E (on ENST00000357308 / NM_001244710.2; = p.D406E on NM_002056.4) | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GLB1L2 | c.1285G>T p.G429W | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GMEB2 | c.70G>C p.D24H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- GRIP2 | c.1444C>G p.R482G (on ENST00000619221; = p.R385G on NM_001080423.4) | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- HEATR5B | c.131A>C p.D44A | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- HECTD1 | c.2527G>C p.D843H | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- HELLS | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HIP1 | c.1086C>G p.F362L | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HJV | c.837_855del p.Y280Sfs*15 (on ENST00000336751 / NM_213653.4; = p.Y167Sfs*15 on NM_145277.5) | Frame Shift Del (DEL) | VAF 13/82 reads (16%) | called by mutect2, pindel*, varscan2*
- HNRNPK | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- IFIT5 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- IFT20 | c.265C>G p.Q89E (on ENST00000395418 / NM_001267776.2; = p.S128* on NM_174887.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- INPPL1 | c.417_438del p.L141Pfs*31 | Frame Shift Del (DEL) | VAF 19/129 reads (15%) | called by mutect2, pindel, varscan2
- IZUMO2 | c.434_439del p.V145_L146del | In Frame Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- JMY | c.814_832del p.G272Pfs*113 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- KALRN | c.8841G>T p.K2947N (on ENST00000360013 / NM_001024660.4; = p.K1250N on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.543); called by muse, mutect2
- KCNJ13 | c.570A>T p.Q190H | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- KIAA0319 | c.2375T>A p.V792D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF4B | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- KLRK1 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KPRP | c.1571A>G p.D524G | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRT19 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.21); called by muse, mutect2
- KRT3 | c.661C>G p.Q221E | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LARP4B | c.1823A>T p.D608V | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.489); called by muse, mutect2
- LILRA1 | c.1396_1434del p.G466_L478del | In Frame Del (DEL) | VAF 29/164 reads (18%) | called by mutect2, pindel
- LNX1 | c.886A>G p.T296A (on ENST00000263925 / NM_001126328.3; = p.T200A on NM_032622.2) | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- LRRC3 | c.589A>G p.S197G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRK1 | c.1639A>T p.S547C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- MAPRE3 | c.165T>G p.C55W | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAT2A | c.757_763del p.G253Lfs*7 | Frame Shift Del (DEL) | VAF 4/39 reads (10%) | called by mutect2, pindel*
- MCF2 | c.2275A>G p.K759E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- MED12L | c.559T>C p.W187R | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- MEOX1 | c.188C>G p.S63* | Nonsense Mutation (SNP) | VAF 11/102 reads (11%) | called by muse, mutect2
- MET | c.3922T>A p.C1308S | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MGA | c.2810A>T p.K937M | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- MICAL2 | c.3073G>A p.E1025K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- MICAL2 | c.4460A>T p.K1487I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- MRPL15 | c.245G>A p.G82E | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- MSR1 | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MTMR12 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC6 | c.1631_1666del p.F544_A555del | In Frame Del (DEL) | VAF 5/41 reads (12%) | called by mutect2, pindel
- MYBL2 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- NAV1 | c.4882G>T p.D1628Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA3 | c.4087A>T p.K1363* (on ENST00000371998 / NM_181659.3; = p.K1359* on NM_006534.4) | Nonsense Mutation (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- NFYA | c.874C>G p.P292A | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- NLRC4 | c.71C>A p.T24K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NOP56 | c.1706G>T p.S569I | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); called by mutect2, varscan2
- NOVA2 | c.558_576del p.E187* | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- NTHL1 | c.436G>T p.V146L (on ENST00000219066; = p.V138L on NM_002528.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/164 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.445); called by muse, mutect2
- NUP133 | c.1100T>C p.L367P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- OMP | c.227G>A p.G76D | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR1N1 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- OR5I1 | c.674T>C p.L225P | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- OSBPL1A | c.2631C>A p.D877E (on ENST00000319481 / NM_080597.4; = p.D364E on NM_018030.4) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAPSS2 | c.658A>C p.I220L | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2
- PARD3B | c.121-11_121del p.X41_splice | Splice Site (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- PCDH9 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB2 | c.847T>C p.F283L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PDE10A | c.909_916del p.D303Efs*10 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel*, varscan2*
- PER2 | c.967+2_967+25del p.X323_splice | Splice Site (DEL) | VAF 4/53 reads (8%) | called by mutect2, pindel
- PGAP6 | c.502T>A p.L168M | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- PHYHIPL | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- PIWIL3 | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.334); called by muse, varscan2
- PKHD1 | c.11498C>T p.S3833F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- PLCG2 | c.8C>G p.T3S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.049); called by muse, mutect2
- PLXDC1 | c.1179del p.T394Qfs*7 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | called by mutect2, pindel, varscan2
- PLXNB3 | c.2470C>A p.P824T | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.62); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PMS2 | c.832C>G p.H278D | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- POLE | c.3490C>G p.P1164A | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PPP1R36 | c.368-32_368del p.X123_splice | Splice Site (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel
- PRB3 | c.344C>G p.P115R | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, varscan2
- PRPF38A | c.393G>C p.K131N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PRRT2 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- PRUNE2 | c.4417G>C p.E1473Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2
- PSEN1 | c.876G>C p.M292I | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PSTPIP1 | c.707A>G p.N236S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- QSER1 | c.4669G>C p.V1557L (on ENST00000399302; = p.V1686L on NM_001076786.3) | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- RAB12 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2
- RALYL | c.37A>T p.K13* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- RIOK2 | c.111G>C p.L37F | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RIOX1 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF169 | c.1892T>A p.L631* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- RNF40 | c.994-1G>C p.X332_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- SACS | c.13466A>G p.D4489G | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SAMD15 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- SATB2 | c.2161G>C p.D721H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.043); called by muse, mutect2
- SCN2B | c.575G>C p.S192T | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SDC4 | c.509A>C p.Y170S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SEMA5B | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SLC12A6 | c.1051G>A p.V351I (on ENST00000354181 / NM_001365088.1; = p.V300I on NM_005135.2) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SLC1A5 | c.1618G>A p.V540I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- SLC22A5 | c.706_707del p.C236Hfs*43 | Frame Shift Del (DEL) | VAF 18/76 reads (24%) | called by pindel, varscan2
- SLC2A1 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- SLC2A11 | c.97T>C p.S33P (on ENST00000345044 / NM_001024938.4; = p.S40P on NM_030807.5) | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by mutect2, varscan2
- SMG1 | c.6187A>T p.K2063* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | called by muse, mutect2, varscan2
- SNTG1 | c.1069T>C p.C357R | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.188); called by muse, mutect2
- SORCS1 | c.1343T>A p.F448Y | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- SRCIN1 | c.730A>T p.I244F (on ENST00000621492; = p.I210F on NM_025248.3) | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- SRP54 | c.25A>C p.K9Q | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.765); called by muse, mutect2
- ST8SIA5 | c.946_951del p.V316_H317del | In Frame Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- STX17 | c.58_91del p.F20Gfs*2 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel
- SUSD4 | c.542T>A p.L181Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SWI5 | c.272A>T p.E91V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SYCP2 | c.3906G>A p.M1302I | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.005); called by muse, mutect2
- SYNE1 | c.7222G>C p.E2408Q (on ENST00000367255 / NM_182961.4; = p.E2415Q on NM_033071.3) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2
- TARS1 | c.70G>A p.E24K | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- TASOR2 | c.7219C>G p.L2407V | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TECPR2 | c.3202G>C p.A1068P | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); called by muse, mutect2
- TENM3 | c.6759A>T p.L2253F | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); called by muse, mutect2
- THNSL1 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TMEM132E | c.1801G>T p.V601L (on ENST00000321639; = p.V691L on NM_001304438.2) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.068); called by mutect2, varscan2
- TMEM135 | c.358A>C p.S120R | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMEM147 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- TP73 | c.695G>C p.G232A | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.041); called by muse, mutect2
- TRPA1 | c.2910T>A p.H970Q | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- TSHR | c.2074C>A p.L692I | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TSPAN1 | c.220G>C p.G74R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTK | c.728+2T>A p.X243_splice | Splice Site (SNP) | VAF 9/48 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.63277C>A p.P21093T (on ENST00000591111; = p.P13669T on NM_003319.4) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- TUT4 | c.395C>T p.P132L | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBA1 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- UNC5C | c.1515G>T p.M505I | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- UPF1 | c.3334T>A p.Y1112N (on ENST00000599848 / NM_001297549.2; = p.Y1101N on NM_002911.4) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- UTRN | c.3101G>C p.G1034A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.642); called by muse, mutect2
- VPS35 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.249); called by muse, mutect2, varscan2
- VSX2 | c.617G>C p.R206P | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- WDR20 | c.1549A>T p.M517L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2
- WDR91 | c.524T>C p.I175T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- WFIKKN2 | c.1017A>T p.E339D | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- XPOT | c.254C>G p.S85* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- ZBTB11 | c.394G>T p.V132F | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); called by muse, mutect2
- ZFHX4 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZIM2 | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ZNF207 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF384 | c.1585del p.Q529Rfs*20 (on ENST00000361959; = p.Q468Rfs*20 on NM_133476.5) | Frame Shift Del (DEL) | VAF 7/54 reads (13%) | called by mutect2, pindel, varscan2
- ZNF460 | c.959G>A p.S320N | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF620 | c.443_458del p.R148Ifs*21 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- ZNF710 | c.774_808del p.T262Afs*8 | Frame Shift Del (DEL) | VAF 42/116 reads (36%) | called by mutect2, pindel
- ZNF749 | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF81 | c.1786C>G p.H596D | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- ABCA13 | c.1812T>C p.S604= | Silent (SNP) | VAF 16/55 reads (29%) | called by muse, mutect2, varscan2
- ABHD6 | c.45G>A p.T15= | Silent (SNP) | VAF 32/65 reads (49%) | called by muse, mutect2, varscan2
- ABI3BP | c.2235T>A p.P745= | Silent (SNP) | VAF 5/91 reads (5%) | called by muse, mutect2
- AC004997.1 | c.1317G>A p.L439= | Silent (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2, varscan2
- ACOT11 | c.447C>T p.F149= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs772387844, COSV100650816, COSV59346499; called by muse, mutect2, varscan2
- AGBL1 | c.3009G>T p.L1003= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- ANK2 | c.2217A>G p.G739= | Silent (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- APOH | c.447G>A p.T149= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as rs372207366; called by muse, mutect2, varscan2
- ARSF | c.102A>C p.L34= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- ATP13A1 | c.3171C>G p.T1057= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV52285399, COSV99179446; called by muse, mutect2, varscan2
- BARHL2 | c.360G>A p.P120= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV64980980; called by muse, varscan2
- BCAS1 | c.246A>G p.K82= | Silent (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- BRPF3 | c.3396G>A p.K1132= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- BSND | c.27C>T p.I9= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs371937424; called by muse, mutect2, varscan2
- CALML3 | c.267C>A p.A89= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- CCNF | c.1056C>G p.L352= | Silent (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
- CERK | c.385A>C p.R129= | Silent (SNP) | VAF 23/110 reads (21%) | called by muse, mutect2, varscan2
- CMYA5 | c.11586G>A p.L3862= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV69745121; called by muse, mutect2, varscan2
- CRACDL | c.228G>A p.E76= | Silent (SNP) | VAF 7/62 reads (11%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.843T>C p.D281= | Silent (SNP) | VAF 12/75 reads (16%) | called by muse, mutect2, varscan2
- EPHB1 | c.2889G>A p.K963= | Silent (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- EXPH5 | c.5139T>C p.H1713= | Silent (SNP) | VAF 6/61 reads (10%) | called by mutect2, varscan2
- FLNC | c.252C>T p.R84= | Silent (SNP) | VAF 14/29 reads (48%) | called by muse, mutect2, varscan2
- FOXB2 | c.114C>T p.D38= | Silent (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- FRY | c.4800G>C p.L1600= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- GAPDHS | c.120A>G p.P40= | Silent (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- GAS2L2 | c.1833C>T p.N611= | Silent (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- GRID1 | c.1863C>T p.G621= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs770151501, COSV60018453; called by muse, mutect2, varscan2
- IRAK2 | c.993C>T p.I331= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV56536417; called by muse, mutect2, varscan2
- ITGA3 | c.1251C>T p.I417= | Silent (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- KIAA0586 | c.216G>A p.V72= (on ENST00000619416 / NM_001244190.2; = p.V87= on NM_014749.5) | Silent (SNP) | VAF 5/67 reads (7%) | catalogued as rs1459167218; called by muse, mutect2
- KLHL12 | c.471T>C p.F157= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1377664989; called by muse, mutect2, varscan2
- KMO | c.639G>A p.L213= | Silent (SNP) | VAF 10/86 reads (12%) | called by muse, mutect2
- LAMA2 | c.7783C>T p.L2595= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- LRRC41 | c.1887C>G p.P629= | Silent (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- MAT2A | c.999C>T p.F333= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV52087401; called by muse, mutect2, varscan2
- MS4A6A | c.210C>T p.S70= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as rs754370880, COSV100124921; called by muse, mutect2
- MTHFD2L | c.351A>G p.L117= (on ENST00000395759 / NM_001144978.2; = p.L59= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs1055906843; called by muse, mutect2, varscan2
- NACC1 | c.1431C>T p.P477= | Silent (SNP) | VAF 20/82 reads (24%) | called by muse, mutect2, varscan2
- NTSR1 | c.591C>T p.A197= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV65139165; called by muse, mutect2, varscan2
- NUP210 | c.3477C>T p.L1159= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as rs202204981; called by muse, mutect2, varscan2
- OR4A47 | c.843C>T p.N281= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as rs766660343; called by muse, mutect2, varscan2
- OR51G1 | c.102C>T p.C34= | Silent (SNP) | VAF 16/45 reads (36%) | called by muse, mutect2, varscan2
- PDSS2 | c.531A>G p.P177= | Silent (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- PEPD | c.1197T>G p.T399= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- PIK3R4 | c.3144C>T p.L1048= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV63240160, COSV63242375; called by muse, mutect2, varscan2
- PIWIL1 | c.855C>T p.N285= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- POLR1B | c.3037A>C p.R1013= | Silent (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- PPP1R26 | c.2187G>A p.T729= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs749263805; called by muse, varscan2
- PRKD2 | c.1311C>T p.Y437= | Silent (SNP) | VAF 6/22 reads (27%) | called by muse, mutect2, varscan2
- PRPF4 | c.981G>A p.R327= (on ENST00000374198 / NM_001322267.2; = p.R328= on NM_004697.5) | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- PRPF8 | c.4173C>G p.L1391= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2, varscan2
- PSMB1 | c.567G>A p.V189= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2
- PTPRZ1 | c.1773C>T p.P591= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as rs753992067; called by muse, mutect2, varscan2
- RBM26 | c.1086C>T p.P362= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV57391273; called by muse, mutect2, varscan2
- RBMXL2 | c.105C>T p.V35= | Silent (SNP) | VAF 38/82 reads (46%) | catalogued as rs1429241139, COSV60979276; called by muse, mutect2, varscan2
- RNF17 | c.4836G>A p.P1612= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs576396754, COSV99692481; called by muse, mutect2, varscan2
- SHOC1 | c.2028C>T p.S676= | Silent (SNP) | VAF 8/72 reads (11%) | called by muse, mutect2
- SMG8 | c.2658C>T p.D886= | Silent (SNP) | VAF 24/72 reads (33%) | called by muse, mutect2, varscan2
- SPATA6 | c.1159T>C p.L387= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- SPG7 | c.1956C>T p.Y652= (on ENST00000268704; = p.Y659= on NM_003119.4) | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV99245109; called by muse, mutect2
- SRMS | c.72C>T p.G24= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs780114763; called by muse, mutect2, varscan2
- SUGP2 | c.2607A>G p.E869= | Silent (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
- THAP3 | c.411C>T p.P137= (on ENST00000054650 / NM_001195753.1; = p.P144= on NM_138350.3) | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- TMEM131L | c.864C>T p.Y288= | Silent (SNP) | VAF 14/70 reads (20%) | catalogued as rs753975812; called by muse, mutect2, varscan2
- TMEM132E | c.1800G>C p.V600= (on ENST00000321639; = p.V690= on NM_001304438.2) | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- TRIM49 | c.39C>G p.L13= | Silent (SNP) | VAF 40/222 reads (18%) | called by mutect2, varscan2
- TSC2 | c.3531G>A p.V1177= | Silent (SNP) | VAF 27/103 reads (26%) | called by muse, mutect2, varscan2
- USP6 | c.1158G>A p.R386= | Silent (SNP) | VAF 12/158 reads (8%) | called by muse, mutect2
- VEZF1 | c.114T>G p.P38= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- ZFP37 | c.1182A>G p.Q394= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs1206556723; called by muse, mutect2
- AP000769.3 | chr11:65503077 G>C | 5'Flank (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499449 T>A | 5'Flank (SNP) | VAF 60/168 reads (36%) | catalogued as rs768068567; called by muse, mutect2, varscan2
- CCDC159 | c.22-679C>T | Intron (SNP) | VAF 9/50 reads (18%) | catalogued as rs767471285; called by muse, mutect2, varscan2
- CCDC30 | c.385-6198A>G | Intron (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- EPDR1 | c.-266A>G | 5'UTR (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- FOXP1 | c.181-17890G>A | Intron (SNP) | VAF 8/56 reads (14%) | catalogued as rs772047806; called by muse, mutect2, varscan2
- HERC2P3 | n.2206C>T | RNA (SNP) | VAF 10/20 reads (50%) | called by mutect2, varscan2
- MSRB3 | c.98-18169T>C | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- NEK11 | c.1399+3880C>T | Intron (SNP) | VAF 15/41 reads (37%) | called by muse, mutect2, varscan2
- OSGIN1 | n.1604G>T | RNA (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- PSG5 | c.431-2974T>C | Intron (SNP) | VAF 55/180 reads (31%) | catalogued as rs1184737728; called by muse, mutect2, varscan2
- SLC16A2 | c.-107G>T | 5'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- TCF7L2 | c.552+49327C>T | Intron (SNP) | VAF 14/52 reads (27%) | catalogued as rs780446801, COSV60503859; called by muse, mutect2, varscan2
- UMODL1 | c.1900-52C>G | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
